Somatic mutation profile of tumor specimen 0DTD39 from CCDI case PBCJHX, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 3.2 years (1,157 days).
Specimen 0DTD39: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 846ee24c-d399-407b-a027-8e24ce188d99.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DTD35 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bccc3fa6-8df6-47c6-99d6-11914ca7af35

The open-access MAF lists 14 somatic variants for this specimen: 12 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 12, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDR2 | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 142/279 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV51676613; called by muse, mutect2, varscan2
- GRID2IP | c.20C>T p.P7L | Missense Mutation (SNP) | VAF 252/421 reads (60%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as rs776424201; called by muse, mutect2, varscan2
- LRRC3C | c.181C>T p.R61W | Missense Mutation (SNP) | VAF 62/145 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.226); catalogued as rs751842501, COSV64987505; called by muse, mutect2, varscan2
- TCHP | c.184C>T p.R62W | Missense Mutation (SNP) | VAF 158/332 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as rs373557911; called by muse, mutect2, varscan2
- FANK1 | c.114A>T p.Q38H | Missense Mutation (SNP) | VAF 160/346 reads (46%) | SIFT tolerated (0.26); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- FBXW11 | c.1003A>C p.T335P | Missense Mutation (SNP) | VAF 171/394 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- LAMC2 | c.3192G>T p.E1064D | Missense Mutation (SNP) | VAF 50/674 reads (7%) | SIFT tolerated (0.42); PolyPhen benign (0.217); called by muse, mutect2
- NIBAN1 | c.488C>A p.P163Q | Missense Mutation (SNP) | VAF 26/731 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PCDHA12 | c.827A>G p.E276G | Missense Mutation (SNP) | VAF 169/605 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- PDE5A | c.1391T>C p.V464A | Missense Mutation (SNP) | VAF 148/347 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.595); called by muse, mutect2, varscan2
- RBMXL3 | c.86G>C p.G29A | Missense Mutation (SNP) | VAF 243/263 reads (92%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- TTC7B | c.1456G>C p.D486H | Missense Mutation (SNP) | VAF 16/430 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- LCP1 | c.21C>T p.S7= | Silent (SNP) | VAF 186/452 reads (41%) | catalogued as rs374341485; called by muse, varscan2
- TBXA2R | c.330C>T p.V110= | Silent (SNP) | VAF 49/180 reads (27%) | catalogued as rs758329601, COSV64343722; called by muse, mutect2, varscan2
